Gene-level copy-number profile of tumor specimen TCGA-95-7567-01A from TCGA case TCGA-95-7567, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.4 years (22,437 days).
Specimen TCGA-95-7567-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.9da27907-449b-4940-82a5-402da92ae91d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-95-7567-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 836 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/069c23d7-320b-4123-8915-4d0289e72cc6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,813; copy number 2: 25,462; copy number 3: 23,851; copy number 4: 4,101; copy number 5: 2,121; copy number 6: 325; copy number 7: 6; copy number 13: 30; copy number 17: 6; copy number 18: 17; copy number 19: 46; copy number 30: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-95-7567-01A-11D-2062-01): tumor purity 0.53, ploidy 2.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,560 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–121,580,524, 78 genes, copy number 5 (broad region; genes not listed).
- chr1:153,586,813–161,964,070, 416 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:166,763,334–248,919,946, 1,667 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:103,855,829–104,722,966, 18 genes, copy number 5 (within-gene range 4–5): AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2.
- chr6:15,102,946–15,663,058, 10 genes, copy number 6: AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P, 5S_rRNA, DTNBP1, AL021978.1.
- chr8:73,688,691–76,308,315, 40 genes, copy number 5 (within-gene range 4–5): AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G, AC011029.1, RNU2-54P.
- chr8:121,612,116–123,274,284, 30 genes, copy number 6 (within-gene range 3–6): HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5.
- chr8:124,306,189–130,443,674, 94 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:141,581,658–141,786,313, 2 genes, copy number 5: AC025839.1, MIR1302-7.
- chr11:100,336,856–104,252,651, 67 genes, copy number 7–30 (broad region; genes not listed).
- chr12:20,962,768–21,775,600, 16 genes, copy number 5 (within-gene range 4–5): SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8.
- chr12:21,828,360–21,828,564, 1 gene, copy number 5: AC008250.2.
- chr12:30,086,342–30,217,916, 3 genes, copy number 5: AC023511.3, AC023511.2, AC023511.1.
- chr18:33,851,100–34,224,952, 1 gene, copy number 13 (within-gene range 4–13): NOL4.
- chr18:34,221,007–36,829,216, 46 genes, copy number 13–18: AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2.
- chr21:27,143,344–30,561,314, 71 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,865. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
